Somatic mutation profile of tumor specimen TCGA-CN-5370-01A (aliquot TCGA-CN-5370-01A-01D-2012-08) from TCGA case TCGA-CN-5370, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 78.2 years (28,549 days).
Specimen TCGA-CN-5370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35838afe-332b-4920-83d3-49fef5f01edb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5370-10A (Blood Derived Normal), aliquot TCGA-CN-5370-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d9572b8-b769-4425-9dfb-c348b7b673c4

The open-access MAF lists 101 somatic variants for this specimen: 80 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Nonsense Mutation 7, Frame Shift Ins 4, Frame Shift Del 3, Splice Site 3, In Frame Del 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2
- ABCA1 | c.2074C>A p.P692T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV66067685; called by muse, mutect2, varscan2
- ADCY9 | c.1124T>A p.I375N | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV53577296; called by muse, mutect2, varscan2
- ALK | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs770435688, COSV66574371; called by muse, mutect2, varscan2
- ANXA1 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 15/134 reads (11%) | catalogued as COSV57411684; called by muse, mutect2, varscan2
- AP1B1 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs753729363, COSV58016568; called by muse, mutect2, varscan2
- ATP13A3 | c.3587G>A p.R1196Q (on ENST00000645319 / NM_001367549.1; = p.R1166Q on NM_024524.3) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1233229224, COSV55466092; called by muse, mutect2
- ATP1A2 | c.2926C>T p.R976C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs371742379; called by muse, mutect2, varscan2
- ATP8B4 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs200106056, COSV52713293; called by muse, mutect2
- BAAT | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200347226, COSV52287019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs200659364, COSV54588594; called by muse, mutect2, varscan2
- CACNA1G | c.5311G>A p.D1771N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.145); catalogued as COSV61730971; called by muse, mutect2, varscan2
- CCDC116 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as rs771117152, COSV53037972; called by muse, mutect2, varscan2
- CCDC125 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as COSV101143479; called by muse, varscan2
- CCNB1IP1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV62303047; called by muse, mutect2, varscan2
- CD200R1L | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV68004540; called by muse, mutect2, varscan2
- CEMIP | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54995198; called by muse, mutect2, varscan2
- CHMP5 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV56303226; called by muse, mutect2, varscan2
- CHSY1 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as COSV54252890, COSV54254344; called by muse, mutect2, varscan2
- DEFB121 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1435295169, COSV66236444; called by muse, mutect2, varscan2
- DNAH11 | c.1320dup p.L441Ifs*25 | Frame Shift Ins (INS) | VAF 10/70 reads (14%) | catalogued as rs1562668233; called by mutect2, varscan2
- DNAH9 | c.2509C>G p.L837V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV52357385; called by muse, mutect2, varscan2
- DOP1A | c.1297_1299del p.Y433del | In Frame Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1324235802; called by pindel, varscan2
- DZIP1 | c.2494G>A p.A832T (on ENST00000347108; = p.A813T on NM_014934.5) | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs147653120; called by muse, mutect2, varscan2
- GBA2 | c.1887T>A p.Y629* | Nonsense Mutation (SNP) | VAF 18/263 reads (7%) | catalogued as COSV62306297; called by muse, mutect2
- GK2 | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV62627449; called by muse, mutect2, varscan2
- GLRA4 | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV65456357; called by muse, mutect2, varscan2
- GPSM2 | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV51443193; called by muse, mutect2, varscan2
- GRIN2B | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1180122833, COSV74206043; called by muse, mutect2, varscan2
- IL2RA | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.095); catalogued as COSV56921480; called by muse, mutect2, varscan2
- ITGA8 | c.2330T>C p.L777P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV65231030; called by muse, mutect2, varscan2
- KMT2D | c.15185G>T p.C5062F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM156347, COSV56473310, COSV99977472; called by muse, mutect2, varscan2
- LDB3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV53944416; called by muse, mutect2, varscan2
- LILRA1 | c.1185C>G p.Y395* | Nonsense Mutation (SNP) | VAF 10/252 reads (4%) | catalogued as COSV99251725; called by muse, mutect2
- LRP4 | c.1166A>T p.D389V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101066220; called by muse, mutect2, varscan2
- MAOA | c.1165-1G>C p.X389_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV58643711; called by muse, mutect2, varscan2
- MUC5B | c.13700C>A p.A4567D | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs749457845, COSV71593431; called by muse, mutect2, varscan2
- MYH7B | c.4759G>A p.E1587K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs779587301, COSV52676922, COSV52681322; called by muse, mutect2, varscan2
- MYO1G | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs774267015, COSV51856660; called by muse, mutect2, varscan2
- NBAS | c.5269G>A p.E1757K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.121); catalogued as rs773927038, COSV55711890; called by muse, mutect2, varscan2
- NCOA6 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); catalogued as rs371910976; called by muse, mutect2, varscan2
- NFATC3 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV60475562; called by muse, mutect2, varscan2
- NLRC4 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV61592174, COSV61592760; called by muse, mutect2, varscan2
- NLRP14 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV55071571; called by muse, mutect2
- OGDH | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV56046808, COSV56055554; called by muse, mutect2, varscan2
- OR2T12 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs200352170, COSV58776065, COSV58778849; called by muse, mutect2, varscan2
- OR6S1 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs989666885, COSV100289264; called by muse, mutect2, varscan2
- OR7A5 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as COSV59234841; called by muse, mutect2, varscan2
- PCDHB10 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 37/199 reads (19%) | catalogued as COSV99503636; called by muse, mutect2, varscan2
- PCDHGC4 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1371072899, COSV52756803, COSV52776879; called by muse, mutect2, varscan2
- PDGFRB | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs150173975, CM150217, COSV55803963; called by muse, mutect2, varscan2
- PEX1 | c.1194C>G p.I398M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV50402622; called by muse, mutect2, varscan2
- PLEKHN1 | c.1694G>T p.G565V (on ENST00000379409; = p.G513V on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs772339258, COSV100378892; called by muse, mutect2, varscan2
- PNPT1 | c.1001A>C p.Y334S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53178134, COSV53180453; called by muse, varscan2
- PRAM1 | c.1431A>G p.I477M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV55314529; called by muse, mutect2, varscan2
- SEMG1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.303); catalogued as rs748751609, COSV54873445; called by muse, mutect2, varscan2
- SEZ6 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57981890; called by muse, mutect2
- SLCO2B1 | c.632T>G p.I211S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56936362; called by muse, mutect2
- SOX13 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99689848; called by muse, mutect2, varscan2
- SYNE1 | c.328A>T p.N110Y (on ENST00000367255 / NM_182961.4; = p.N117Y on NM_033071.3) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55019814; called by muse, mutect2, varscan2
- TEX14 | c.1924A>G p.I642V (on ENST00000240361 / NM_001201457.2; = p.I636V on NM_031272.5) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV53620035; called by muse, mutect2, varscan2
- TLN1 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 262/453 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV59208831; called by muse, mutect2, varscan2
- TMEM202 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); catalogued as COSV58982919; called by muse, mutect2, varscan2
- TMTC4 | c.859C>T p.R287C (on ENST00000376234 / NM_001350577.2; = p.R306C on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141063052; called by muse, mutect2
- TRPM1 | c.4381A>G p.I1461V | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs1391166889, COSV56636924; called by muse, mutect2, varscan2
- TTN | c.46741G>A p.V15581M (on ENST00000591111; = p.V8157M on NM_003319.4) | Missense Mutation (SNP) | VAF 16/448 reads (4%) | PolyPhen possibly damaging (0.81); catalogued as COSV100593855, COSV60364730; called by muse, mutect2
- UACA | c.2281A>G p.I761V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59857061; called by muse, mutect2, varscan2
- UNC13B | c.2848-1G>C p.X950_splice | Splice Site (SNP) | VAF 18/222 reads (8%) | catalogued as COSV65935847; called by muse, mutect2
- VWA3B | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs777197115, COSV101289408; called by muse, mutect2, varscan2
- VWA8 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1374603133, COSV55699201; called by muse, mutect2, varscan2
- ELN | c.1446_1463del p.V491_G496del | In Frame Del (DEL) | VAF 68/370 reads (18%) | called by mutect2, varscan2
- FAT1 | c.7851del p.V2618Ffs*25 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel, varscan2
- FAT1 | c.1402_1406del p.Y468Sfs*4 | Frame Shift Del (DEL) | VAF 51/249 reads (20%) | called by mutect2, pindel, varscan2
- GATAD2B | c.627dup p.V210Cfs*15 | Frame Shift Ins (INS) | VAF 21/134 reads (16%) | called by mutect2, pindel, varscan2
- IGKV1-8 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- IVNS1ABP | c.736_737dup p.S246Rfs*23 | Frame Shift Ins (INS) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- MYH9 | c.514dup p.C172Lfs*4 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- SPECC1 | c.1755del p.V586* | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by mutect2, pindel, varscan2
- ABCA6 | c.3042G>A p.P1014= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs750465021, COSV52640568; called by muse, mutect2, varscan2
- CCNL2 | c.999C>T p.P333= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as COSV68766800; called by muse, mutect2, varscan2
- EMD | c.246T>A p.A82= | Silent (SNP) | VAF 70/153 reads (46%) | catalogued as COSV63962294; called by muse, mutect2, varscan2
- EXD2 | c.864C>T p.V288= (on ENST00000312994 / NM_001193362.1; = p.V163= on NM_018199.3) | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs775769920, COSV57280353; called by muse, mutect2, varscan2
- FAM47B | c.531C>T p.T177= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs149160457, COSV100264047; called by muse, mutect2, varscan2
- FGD2 | c.1260C>T p.I420= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs991080966, COSV51464371; called by muse, mutect2, varscan2
- HADH | c.378G>A p.V126= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV58847379; called by muse, mutect2, varscan2
- HRH1 | c.222G>A p.L74= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV101229034; called by muse, mutect2, varscan2
- IRAK1 | c.678G>T p.V226= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV57654938; called by muse, mutect2, varscan2
- LLGL2 | c.2337C>A p.I779= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99388910; called by muse, mutect2, varscan2
- NOLC1 | c.2019G>A p.E673= | Silent (SNP) | VAF 60/369 reads (16%) | catalogued as COSV64180650; called by muse, mutect2, varscan2
- PRAF2 | c.168C>T p.L56= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs782356172, COSV59876210, COSV59876306; called by muse, mutect2, varscan2
- RAPGEF5 | c.924C>G p.L308= (on ENST00000401957 / NM_001367602.2; = p.L611= on NM_012294.5) | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV59786260; called by muse, mutect2
- SOCS3 | c.273G>A p.K91= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV58270748; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.33G>C p.L11= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs944309610, COSV50076067; called by muse, mutect2, varscan2
- TPH2 | c.1341C>T p.F447= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV61592711; called by muse, mutect2, varscan2
- ZFP36L1 | c.231C>T p.P77= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100322428; called by muse, mutect2, varscan2
- ZXDC | c.1771C>T p.L591= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV60447508; called by muse, mutect2, varscan2
- MIR363 | n.20A>T | RNA (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- SNORD115-18 | n.31G>A | RNA (SNP) | VAF 18/323 reads (6%) | called by muse, mutect2
- ZNF419 | c.298+12G>A | Intron (SNP) | VAF 29/119 reads (24%) | catalogued as COSV99691792; called by muse, mutect2, varscan2
